Somatic mutation profile of tumor specimen TARGET-30-PASWIJ-01A (aliquot TARGET-30-PASWIJ-01A-01D) from TARGET case TARGET-30-PASWIJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.9 years (2,537 days).
Specimen TARGET-30-PASWIJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ba9e431-eb06-4a53-a8c7-c762a6af047e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASWIJ-10A (Blood Derived Normal), aliquot TARGET-30-PASWIJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6139f1be-c118-4991-a1bb-d61ba748fa9c

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, 5'Flank 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV68630159; called by mutect2, varscan2
- ANKRD50 | c.3203G>T p.G1068V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV72386350; called by muse, mutect2, varscan2
- ATP8B4 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52725036; called by muse, mutect2
- CCN2 | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs759434407, COSV63467049; called by muse, mutect2, varscan2
- CD1C | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63807771; called by mutect2, varscan2
- CELSR2 | c.4881G>T p.W1627C | Missense Mutation (SNP) | VAF 178/503 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54779790, COSV99603812; called by muse, mutect2, varscan2
- DOCK1 | c.1618del p.D540Mfs*29 | Frame Shift Del (DEL) | VAF 48/155 reads (31%) | catalogued as COSV54761409; called by mutect2, pindel, varscan2
- FAT1 | c.5328A>T p.E1776D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71676299; called by muse, mutect2
- FREM2 | c.4247G>A p.S1416N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs908015419, COSV54853597; called by muse, varscan2
- MX2 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs532773256, COSV58099725; called by muse, mutect2, varscan2
- NPHP1 | c.2002C>T p.R668C (on ENST00000393272 / NM_207181.4; = p.R669C on NM_000272.5) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs543675502, COSV57212042; ClinVar: uncertain significance; called by mutect2, varscan2
- OR52E2 | c.794T>A p.F265Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV58613678; called by muse, mutect2, varscan2
- OR52E8 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV66211395; called by muse, mutect2, varscan2
- OR52I1 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1391201275; called by muse, mutect2, varscan2
- PKP2 | c.1750G>C p.D584H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776922980, COSV50750192, COSV99298488; called by muse, mutect2, varscan2
- SCRT2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs756968855, COSV55730612; called by mutect2, varscan2
- SLC22A5 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs886042092, CM102256, COSV55373865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX9 | c.349G>T p.G117W | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV67586173; called by muse, mutect2, varscan2
- STAB1 | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs200287966; called by muse, mutect2, varscan2
- STOML3 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65512019; called by muse, mutect2, varscan2
- STYK1 | c.224G>C p.W75S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV50012536, COSV50015685; called by muse, mutect2, varscan2
- TNFRSF11A | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs781169173, COSV54026311; called by muse, mutect2, varscan2
- TONSL | c.2143C>A p.H715N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV101340258; called by mutect2, varscan2
- TROAP | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs760779772, COSV57746113; called by muse, mutect2, varscan2
- XKR6 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753755136, COSV58659784; called by mutect2, varscan2
- ZMAT4 | c.297C>A p.H99Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52708095, COSV52715861; called by muse, mutect2, varscan2
- COBL | c.2598G>C p.Q866H | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF3G | c.675C>G p.R225= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53456170; called by muse, mutect2, varscan2
- EPB41L2 | c.1854A>G p.E618= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV61359296; called by muse, mutect2, varscan2
- FLT4 | c.2076C>T p.S692= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV56103072; called by mutect2, varscan2
- KCNN3 | c.1695A>G p.K565= (on ENST00000618040 / NM_001204087.1; = p.K550= on NM_002249.6) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs762109698, COSV55227557; called by muse, mutect2, varscan2
- MAD1L1 | c.1911C>T p.T637= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs373029162, COSV56248462, COSV99766030; called by mutect2, varscan2
- SERPINI2 | c.222T>C p.T74= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV52989081, COSV99248040; called by muse, mutect2, varscan2
- SPACA6 | chr19:51692680 T>C | 5'Flank (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- SPACA6 | chr19:51692681 C>G | 5'Flank (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SSPOP | n.15676G>T | RNA (SNP) | VAF 12/66 reads (18%) | catalogued as COSV65133344, COSV65137184; called by muse, mutect2, varscan2
